Somatic mutation profile of tumor specimen TCGA-ZB-A96H-01A (aliquot TCGA-ZB-A96H-01A-11D-A428-09) from TCGA case TCGA-ZB-A96H, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 73.1 years (26,683 days).
Specimen TCGA-ZB-A96H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffbe1e76-2833-4ddf-97e5-aa1438f207bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96H-10A (Blood Derived Normal), aliquot TCGA-ZB-A96H-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75749f7d-aa0b-4fc5-bd8e-c61d283bfe0f

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 152/458 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LIN9 | c.1111C>T p.R371W (on ENST00000366808 / NM_001270410.2; = p.R316W on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs761143720; called by muse, mutect2, varscan2
- MYOF | c.4391A>G p.H1464R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs1027796845; called by muse, mutect2
- SEC23A | c.1937G>C p.R646P | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV56979022; called by muse, mutect2, varscan2
- SLC66A1 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs143243971, COSV64320854; called by muse, mutect2, varscan2
- CD226 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL12A1 | c.4822A>G p.K1608E | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- NLRC4 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- OPRL1 | c.976T>C p.F326L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PDGFB | c.391T>C p.S131P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PKP4 | c.3029A>G p.H1010R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2
- SLC25A46 | c.146T>G p.I49S | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- UBA6 | c.2904del p.L969Wfs*4 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- DCAF12L2 | c.1269C>T p.G423= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- FCGBP | c.10191C>A p.R3397= | Silent (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
